Surgical pathology report (de-identified scan), TCGA case TCGA-SP-A6QI, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site University Health Network, specimen TCGA-SP-A6QI-01A (Primary Tumor).

[page 1 of 2]
LABORATORY MEDICINE PROGRAM

Surgical Pathology Consultation Report

Patient Name: [REDACTED]

MRN: [REDACTED]

DOB: [REDACTED]

Gender: [REDACTED]

HCN: [REDACTED]

Ordering MD: [REDACTED]

Copy To: [REDACTED]

Service: [REDACTED]
Visit #: [REDACTED]

Location: [REDACTED]
Facility: [REDACTED]

Accession #: [REDACTED]

Collected: [REDACTED]

Received: [REDACTED]

Reported: [REDACTED]

Specimen(s) Received

1. Adrenal: right adrenal gland

Diagnosis

Pheochromocytoma: Adrenal (right) adrenalectomy specimen

Comment

This is an unusual pheochromocytoma. The architecture and cytology mimic a cortical lesion, but the immunohistochemistry identifies the correct diagnosis.

Electronically verified by: [REDACTED]

Clinical History

None

Gross Description

The specimen container labeled with the patient's name and as "right adrenal gland" contains an adrenal gland with a mass. The specimen weighs 39.0 grams and measures 9.0 x 4.7 x 2.5 cm. The external surface is painted with silver nitrate. After removal of adherent fat, the adrenal weighs 33.5 grams. On section there is a well-delineated mass that measures 3.4 x 3.2 x 3.0 cm and has a solid bright yellow to yellow-orange homogenous cut surface. The remainder of the adrenal is unremarkable. The specimen is submitted in toto as follows:

- 1A-M mass from one end to the other
- 1N-X remainder of the adrenal gland

Microscopic Description

DOMINANT LESION: adrenal tumor

SIZE: 9.0 cm maximum dimension

WEIGHT: 33.5 g

ARCHITECTURE: solid nesting and trabecular architecture

CYTOLOGY: round cells with well-defined cell borders, abundant clear to basophilic cytoplasm and no nuclear pleomorphism

DEGENERATION: none identified

ENCAPSULATION: incomplete capsule

CAPSULAR INVASION: no frank invasion identified

[page 2 of 2]
Surgical Pathology Consultation Report

EXTRA-ADRENAL INVASION: not identified

RESECTION MARGINS: not involved

LYMPHOVASCULAR INVOLVEMENT: not identified

OTHER ADRENAL PATHOLOGY: none; no cortical atrophy or hyperplasia and no medullary hyperplasia

LYMPH NODES: none identified

IMMUNOHISTOCHEMISTRY: positive for chromogranin and tyrosine hydroxylase; sustentacular cells stain for S100 protein

Source: NCI Genomic Data Commons file 151a0b80-8aad-4b8f-b96a-745ea85be57f (TCGA-SP-A6QI.2022A9E9-FCAD-4B04-A732-4FFDB416B972.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).